Somatic mutation profile of tumor specimen 0DDKE0 from CCDI case PBBNEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 14.1 years (5,165 days).
Specimen 0DDKE0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6879d36a-ffeb-433c-b62b-f617545723c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKE1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8f21d77-2fc8-4e2c-ac4f-99d6d399fb9d

The open-access MAF lists 64 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 17, 3'UTR 4, Intron 4, 5'Flank 3, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 162/240 reads (68%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.2730A>C p.E910D | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as rs781438370; called by muse, mutect2
- ARHGAP5 | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100565169; called by muse, mutect2, varscan2
- CCDC107 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV58398443; called by muse, mutect2, varscan2
- CLSTN3 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs753953488; called by muse, mutect2
- CRYBG3 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs751013028; called by muse, mutect2, varscan2
- FADS2 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 26/672 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53897204; called by muse, mutect2
- KIF5A | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54054676; called by muse, mutect2
- LCN9 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.932); catalogued as rs756033576; called by muse, mutect2, varscan2
- NKX6-2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs138717832; called by muse, mutect2, varscan2
- PSMD12 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1186535141, COSV62066631; called by muse, mutect2
- SLC16A7 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99676590; called by muse, mutect2
- SPATA31A6 | c.1511C>A p.P504Q | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV60535398, COSV60535838; called by muse, mutect2, varscan2
- ZBTB46 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.61); catalogued as COSV99828705; called by muse, mutect2
- ADGRG6 | c.2425A>C p.N809H | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ADGRG6 | c.2629_2633del p.I877Ffs*12 | Frame Shift Del (DEL) | VAF 93/358 reads (26%) | called by mutect2, pindel, varscan2
- ANAPC7 | c.1113_1114del p.N371Kfs*8 | Frame Shift Del (DEL) | VAF 114/444 reads (26%) | called by mutect2, pindel, varscan2
- ANK2 | c.8248G>A p.V2750I | Missense Mutation (SNP) | VAF 105/478 reads (22%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2
- BTRC | c.1807A>G p.I603V (on ENST00000370187 / NM_033637.4; = p.I567V on NM_003939.5) | Missense Mutation (SNP) | VAF 83/462 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D1A | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 176/425 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- CDC7 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 18/411 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.11969C>T p.S3990L | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT5 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 27/378 reads (7%) | called by muse, mutect2
- GANC | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 70/288 reads (24%) | called by muse, mutect2, varscan2
- HIPK4 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by muse, mutect2
- LGALS8 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPL | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MXRA5 | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 148/177 reads (84%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE8B | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 45/450 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PIK3C2G | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 22/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCE1 | c.3116G>A p.G1039D | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SCN10A | c.476T>A p.V159D | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SI | c.4940T>A p.V1647E | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF503 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ALDH5A1 | c.606C>T p.T202= | Silent (SNP) | VAF 30/444 reads (7%) | called by muse, mutect2
- ASB18 | c.477C>T p.A159= | Silent (SNP) | VAF 47/258 reads (18%) | called by muse, mutect2, varscan2
- ATXN1L | c.501C>T p.A167= | Silent (SNP) | VAF 113/351 reads (32%) | called by muse, mutect2, varscan2
- BSN | c.5664C>T p.D1888= | Silent (SNP) | VAF 119/338 reads (35%) | catalogued as rs1476030484; called by muse, mutect2, varscan2
- CHRFAM7A | c.708G>A p.K236= | Silent (SNP) | VAF 64/383 reads (17%) | called by muse, mutect2, varscan2
- CMPK1 | c.51C>T p.F17= | Silent (SNP) | VAF 35/325 reads (11%) | catalogued as rs778256325; called by muse, mutect2, varscan2
- DOCK4 | c.2301C>T p.F767= | Silent (SNP) | VAF 120/338 reads (36%) | catalogued as rs539313388; called by muse, varscan2
- FBXL7 | c.1080C>T p.C360= | Silent (SNP) | VAF 61/315 reads (19%) | catalogued as rs1324931908; called by muse, mutect2, varscan2
- FCRL1 | c.708T>G p.P236= | Silent (SNP) | VAF 36/591 reads (6%) | called by muse, mutect2
- FSTL4 | c.1356C>T p.N452= | Silent (SNP) | VAF 24/382 reads (6%) | called by muse, mutect2
- GBX1 | c.312G>A p.A104= | Silent (SNP) | VAF 62/354 reads (18%) | called by muse, mutect2, varscan2
- GPR85 | c.465C>T p.P155= | Silent (SNP) | VAF 36/890 reads (4%) | catalogued as COSV51785709; called by muse, mutect2
- IGF2R | c.5340C>T p.T1780= | Silent (SNP) | VAF 50/395 reads (13%) | catalogued as rs749143547; called by muse, mutect2, varscan2
- NELL2 | c.1755T>C p.D585= | Silent (SNP) | VAF 116/386 reads (30%) | called by muse, mutect2, varscan2
- OR2B6 | c.595C>T p.L199= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- PIK3CG | c.633G>A p.L211= | Silent (SNP) | VAF 138/410 reads (34%) | called by muse, mutect2, varscan2
- ZHX1 | c.573G>A p.V191= | Silent (SNP) | VAF 26/518 reads (5%) | called by muse, mutect2
- B4GALT3 | c.*6_*8del | 3'UTR (DEL) | VAF 60/330 reads (18%) | catalogued as rs760228954; called by pindel, varscan2
- CREB3L1 | c.596-33C>T | Intron (SNP) | VAF 132/219 reads (60%) | catalogued as rs374891862; called by muse, mutect2, varscan2
- ENPP4 | c.*58C>T | 3'UTR (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- HOXD10 | c.*31C>T | 3'UTR (SNP) | VAF 91/226 reads (40%) | called by muse, mutect2, varscan2
- INPP5K | c.554+31C>T | Intron (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- NFIA | chr1:61081896 G>C | 5'Flank (SNP) | VAF 12/110 reads (11%) | catalogued as rs1330078624, COSV100964177; called by muse, mutect2, varscan2
- PCSK4 | c.855+12C>T | Intron (SNP) | VAF 34/444 reads (8%) | called by muse, mutect2
- PLEKHG4B | chr5:140198 G>T | 5'Flank (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- SSNA1 | chr9:137188675 C>T | 5'Flank (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- TBCA | c.*36C>T | 3'UTR (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
- TM2D1 | c.-92G>T | 5'UTR (SNP) | VAF 24/118 reads (20%) | catalogued as COSV53910113; called by muse, mutect2, varscan2
- TRA2A | c.838+33C>T | Intron (SNP) | VAF 25/226 reads (11%) | catalogued as COSV99767472; called by muse, mutect2, varscan2
